Somatic mutation profile of tumor specimen TCGA-B1-A656-01A (aliquot TCGA-B1-A656-01A-11D-A31X-10) from TCGA case TCGA-B1-A656, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.9 years (23,702 days).
Specimen TCGA-B1-A656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb7de1dd-8aa3-431d-b9c6-a3393d229515.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-A656-10A (Blood Derived Normal), aliquot TCGA-B1-A656-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5031dbfb-4fc5-40c5-b57d-49a7f57e212f

The open-access MAF lists 119 somatic variants for this specimen: 92 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 25, Nonsense Mutation 9, Frame Shift Del 6, Frame Shift Ins 4, Intron 2, In Frame Del 2, Splice Site 2, In Frame Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.8257G>A p.D2753N | Missense Mutation (SNP) | VAF 105/516 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV71296351; called by muse, mutect2, varscan2
- ACSM2A | c.1232G>A p.G411D (on ENST00000219054; = p.G332D on NM_001308169.2) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54591147; called by muse, mutect2, varscan2
- ADAMTS15 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54510543; called by muse, mutect2, varscan2
- ALOX5 | c.1220T>A p.I407N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65555199; called by muse, mutect2, varscan2
- ANK1 | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs767553149, COSV55899058; called by muse, mutect2, varscan2
- ASB6 | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV52966095; called by muse, mutect2, varscan2
- ASMTL | c.1185C>G p.I395M | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV101188002, COSV67245408; called by muse, mutect2, varscan2
- ATRN | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53536059; called by muse, varscan2
- BACE1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57286776; called by muse, mutect2, varscan2
- BCAR3 | c.2090C>G p.S697C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV53076364, COSV53080413; called by muse, mutect2, varscan2
- BRCA2 | c.4405G>T p.D1469Y | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as CD152254, COSV66464041; called by muse, mutect2, varscan2
- CEP192 | c.3214A>T p.T1072S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV58071995; called by muse, varscan2
- CLASRP | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); catalogued as COSV55520175; called by muse, mutect2, varscan2
- CLPB | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.203); catalogued as COSV53634785; called by muse, mutect2, varscan2
- CNTNAP5 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV70477933, COSV70519006; called by muse, mutect2, varscan2
- CYP2F1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58529125; called by muse, mutect2, varscan2
- CYP4F3 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as COSV55414462; called by muse, mutect2, varscan2
- DENND6A | c.1422A>C p.L474F | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV60770548; called by muse, mutect2, varscan2
- DPY30 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV54460015; called by muse, mutect2, varscan2
- DYNC2H1 | c.9025C>G p.P3009A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV62110085; called by mutect2, varscan2
- EIF2D | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55116090; called by muse, mutect2, varscan2
- ENG | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs199764615, COSV61229442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPAS1 | c.1976C>G p.T659R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.06); catalogued as COSV55391200; called by muse, varscan2
- F2R | c.1240A>G p.N414D | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV59930512; called by muse, mutect2, varscan2
- FAM13A | c.2612A>T p.E871V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52015545; called by muse, mutect2, varscan2
- FBXL22 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs775727167, COSV62216536; called by muse, mutect2, varscan2
- FDXR | c.396C>T p.S132= | Splice Region (SNP) | VAF 11/69 reads (16%) | catalogued as COSV53126017; called by muse, mutect2, varscan2
- FGR | c.605A>T p.K202I | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV64969908; called by muse, mutect2, varscan2
- FZD4 | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV72294798; called by muse, mutect2, varscan2
- GABRD | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772295324, COSV66081745; called by muse, mutect2
- GORAB | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV63027144; called by muse, mutect2, varscan2
- GUCY2C | c.347G>C p.G116A | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs761090634, COSV53797086; called by muse, mutect2, varscan2
- HIBCH | c.1130A>G p.K377R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV61411028; called by muse, mutect2, varscan2
- HS3ST3A1 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV52375723, COSV52380253; called by muse, mutect2, varscan2
- KCNE3 | c.260A>T p.K87M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59552775; called by muse, mutect2, varscan2
- KCNE3 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV59552782; called by muse, mutect2, varscan2
- KLF5 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs200707995, COSV66615750; called by muse, mutect2, varscan2
- LGR4 | c.831-1G>C p.X277_splice | Splice Site (SNP) | VAF 71/214 reads (33%) | catalogued as COSV64866810; called by muse, mutect2, varscan2
- LMTK2 | c.4324T>G p.S1442A | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV52006282; called by muse, mutect2, varscan2
- LRIG3 | c.2785A>C p.M929L | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV100292816, COSV57871375; called by muse, mutect2, varscan2
- LRRC57 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53001545; called by muse, mutect2, varscan2
- LTBP4 | c.3781C>T p.R1261* (on ENST00000308370 / NM_001042544.1; = p.R1224* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV52592897; called by muse, mutect2, varscan2
- MRPS15 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64152824; called by muse, mutect2, varscan2
- NBR1 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57836480; called by muse, mutect2, varscan2
- NTRK3 | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.244); catalogued as rs1319972647, COSV58129193, COSV58149593; called by muse, mutect2, varscan2
- NUDT13 | c.214A>C p.S72R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV61970346; called by muse, mutect2, varscan2
- PBRM1 | c.1861A>T p.K621* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV56310441; called by muse, mutect2, varscan2
- PHLPP1 | c.1559T>A p.L520H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53041494; called by muse, mutect2, varscan2
- PLCB3 | c.3466C>T p.Q1156* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV54193052; called by muse, mutect2, varscan2
- PNCK | c.494C>G p.A165G (on ENST00000340888 / NM_001366975.1; = p.A248G on NM_001039582.3) | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0.063); catalogued as COSV61745867; called by muse, mutect2, varscan2
- PSG9 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV52489148; called by muse, mutect2, varscan2
- PYDC1 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.342); catalogued as rs1567493160, COSV57252518; called by muse, mutect2, varscan2
- RASEF | c.933T>A p.Y311* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV64589236; called by muse, mutect2, varscan2
- RFX3 | c.1121G>C p.S374T | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV56527130; called by muse, mutect2, varscan2
- RPRML | c.291C>A p.S97R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59263053; called by muse, mutect2, varscan2
- SH3TC1 | c.2725T>C p.F909L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV55291309; called by muse, mutect2, varscan2
- SHC4 | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs1278724959, COSV60118353; called by muse, mutect2, varscan2
- SNRK | c.1097A>T p.K366I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV56071717; called by muse, mutect2, varscan2
- SORCS1 | c.2958C>A p.N986K | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV53915404; called by muse, mutect2, varscan2
- SPINT1 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV59803984; called by muse, mutect2, varscan2
- SQSTM1 | c.427A>T p.S143C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV62435996; called by muse, mutect2, varscan2
- SRRT | c.2368C>A p.Q790K | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV53822604; called by muse, mutect2, varscan2
- STXBP1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as COSV64815837; called by muse, mutect2, varscan2
- TEDDM1 | c.610T>C p.W204R | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62380818; called by muse, mutect2, varscan2
- THBS1 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52956593; called by muse, mutect2, varscan2
- TIAM1 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54580461; called by muse, mutect2, varscan2
- TMEM131L | c.3686C>A p.S1229* | Nonsense Mutation (SNP) | VAF 178/615 reads (29%) | catalogued as COSV53649275, COSV53651751; called by muse, mutect2, varscan2
- TNRC6A | c.1358C>G p.P453R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59365187, COSV59371514; called by muse, mutect2, varscan2
- TP53BP2 | c.2610G>T p.E870D (on ENST00000343537 / NM_001031685.3; = p.E741D on NM_005426.2) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV59074060; called by muse, mutect2, varscan2
- UIMC1 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV65895477; called by muse, mutect2, varscan2
- UNC5A | c.2020-1G>A p.X674_splice | Splice Site (SNP) | VAF 24/107 reads (22%) | catalogued as COSV52844818; called by muse, mutect2, varscan2
- ZIM2 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV55651842; called by muse, mutect2, varscan2
- ZMIZ1 | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV57905625; called by muse, mutect2, varscan2
- ZNF426 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53471124; called by muse, mutect2, varscan2
- ZNF558 | c.472T>C p.F158L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as COSV56864716; called by muse, mutect2, varscan2
- ZNF836 | c.623T>A p.L208H | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.431); catalogued as COSV59087657; called by muse, mutect2, varscan2
- ALS2 | c.4372_4385delinsAT p.S1458_S1462delinsI | In Frame Del (DEL) | VAF 57/281 reads (20%) | called by pindel, varscan2*
- C12orf40 | c.796del p.I266Yfs*19 | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | called by mutect2, pindel, varscan2
- CDHR3 | c.2564del p.G855Vfs*20 | Frame Shift Del (DEL) | VAF 33/170 reads (19%) | called by mutect2, pindel, varscan2
- DLD | c.862A>T p.K288* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | called by mutect2, varscan2
- HOXB4 | c.46_48dup p.K16dup | In Frame Ins (INS) | VAF 46/161 reads (29%) | called by mutect2, varscan2
- MCF2L | c.766dup p.A256Gfs*2 (on ENST00000375608; = p.A224Gfs*2 on NM_024979.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- MTMR14 | c.930_933delinsGA p.Y310* | Nonsense Mutation (DEL) | VAF 70/138 reads (51%) | called by pindel, varscan2*
- MYH14 | c.2429del p.F810Sfs*24 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- OR5P2 | c.72_73insTT p.I25Lfs*9 | Frame Shift Ins (INS) | VAF 16/67 reads (24%) | called by mutect2, varscan2*
- OR5P2 | c.70_71del p.P24Nfs*14 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, varscan2*
- PARP1 | c.2178_2180del p.S727del | In Frame Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- PIR | c.773_775dup p.M258dup | In Frame Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- PLCZ1 | c.248dup p.N83Kfs*9 | Frame Shift Ins (INS) | VAF 62/151 reads (41%) | called by mutect2, varscan2
- REV1 | c.3339dup p.D1114* | Frame Shift Ins (INS) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- SLC20A2 | c.724del p.I242* | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | called by mutect2, pindel, varscan2
- SLC24A2 | c.1770del p.H591Tfs*38 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- ACOT9 | c.1029C>T p.I343= | Silent (SNP) | VAF 92/150 reads (61%) | catalogued as COSV60539203; called by muse, mutect2, varscan2
- ADCY7 | c.1545C>T p.N515= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs144290211; called by muse, varscan2
- ARID1A | c.4200T>C p.P1400= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV61391265; called by muse, mutect2, varscan2
- CABLES1 | c.1182G>A p.G394= (on ENST00000256925 / NM_001100619.2; = p.G129= on NM_138375.2) | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV56938452; called by muse, mutect2, varscan2
- CADPS2 | c.2319T>C p.G773= | Silent (SNP) | VAF 75/392 reads (19%) | catalogued as COSV57391042; called by muse, varscan2
- COL19A1 | c.867A>G p.P289= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs1218691273, COSV59592217; called by muse, mutect2, varscan2
- DHX16 | c.2952G>T p.L984= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV53316334; called by muse, varscan2
- FEM1A | c.954C>A p.A318= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs745400673, COSV54163109, COSV54165193; called by muse, mutect2, varscan2
- GGNBP2 | c.786C>T p.C262= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as rs779575680; called by muse, mutect2, varscan2
- GPN3 | c.129A>G p.A43= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV57402959; called by muse, mutect2, varscan2
- HDAC11 | c.240T>G p.L80= | Silent (SNP) | VAF 58/96 reads (60%) | catalogued as COSV55474855; called by muse, mutect2, varscan2
- ICAM3 | c.1608A>T p.T536= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs369252388; called by muse, mutect2, varscan2
- LARP6 | c.219A>G p.G73= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV54583147; called by muse, mutect2, varscan2
- MYCN | c.72A>G p.L24= | Silent (SNP) | VAF 55/202 reads (27%) | catalogued as rs1301969878, COSV55259120; called by muse, mutect2, varscan2
- N4BP1 | c.2532C>T p.P844= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs758763790, COSV52214147; called by muse, mutect2, varscan2
- NAALADL1 | c.1623C>T p.Y541= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs1357101901, COSV60522816, COSV60526500; called by muse, mutect2, varscan2
- NCOA4 | c.1272G>A p.K424= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as rs782299744; called by muse, mutect2, varscan2
- NEU2 | c.343C>T p.L115= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV52094435; called by muse, mutect2, varscan2
- NPFFR2 | c.894C>G p.S298= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV58155716; called by muse, mutect2, varscan2
- OR4K17 | c.96G>A p.S32= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as rs138358295; called by muse, mutect2, varscan2
- TRAK1 | c.360G>A p.E120= (on ENST00000327628 / NM_001349247.2; = p.E62= on NM_014965.5) | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV58258214, COSV58265945; called by muse, mutect2, varscan2
- TRIL | c.1179C>T p.P393= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV59868240; called by muse, mutect2, varscan2
- ZMAT1 | c.405T>A p.I135= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV65660463; called by muse, mutect2, varscan2
- ZNF506 | c.936C>G p.P312= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV71354848; called by muse, mutect2, varscan2
- ZNF830 | c.192C>A p.L64= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV58492513; called by muse, mutect2, varscan2
- GON4L | c.4473+47T>C | Intron (SNP) | VAF 82/290 reads (28%) | catalogued as COSV99674946; called by muse, mutect2, varscan2
- NACA | c.71-3796C>A | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs567109246, COSV100771441; called by muse, mutect2, varscan2
